CCDI case PBBUTV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and ill-defined digestive organs.
https://portal.gdc.cancer.gov/cases/431e4b1f-f88c-425f-abe9-2dbf781b17e4

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Desmoplastic small round cell tumor: ICD-O-3 morphology code: 8806/3; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 23.4 years (8,532 days).

Biospecimens (3 samples)
- Sample 0DIOJW: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIOK5: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIOKD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
